Somatic mutation profile of tumor specimen TCGA-58-8387-01A (aliquot TCGA-58-8387-01A-11D-2293-08) from TCGA case TCGA-58-8387, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,952 days).
Specimen TCGA-58-8387-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e73f972-3056-4982-a4a8-02d42906c1db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8387-10A (Blood Derived Normal), aliquot TCGA-58-8387-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd0edced-b810-4279-8b63-8cd685144d76

The open-access MAF lists 199 somatic variants for this specimen: 132 protein-altering or splice-affecting, 56 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 56, Nonsense Mutation 11, Intron 6, Splice Site 3, RNA 2, Frame Shift Del 2, 3'UTR 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 45/176 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100299167; called by muse, mutect2, varscan2
- ABCC3 | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 125/432 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV99558740; called by muse, mutect2, varscan2
- ACSM2A | c.1189G>A p.D397N (on ENST00000219054; = p.D318N on NM_001308169.2) | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs750637232, COSV54582503; called by muse, mutect2, varscan2
- AFF1 | c.2582A>G p.K861R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV100320239; called by muse, mutect2, varscan2
- AFM | c.585A>T p.E195D | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); catalogued as COSV99888524; called by muse, mutect2
- AGR3 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV100123877; called by muse, mutect2, varscan2
- ANKRD55 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as rs199752327, COSV61951583; called by muse, mutect2
- ARHGAP35 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101350735; called by muse, mutect2, varscan2
- ARHGEF11 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV100168309; called by muse, mutect2
- ASIC4 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100761575; called by muse, mutect2, varscan2
- BOC | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56353242, COSV99848200; called by muse, mutect2, varscan2
- C19orf18 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs780592836, COSV100071660; called by muse, mutect2, varscan2
- C6orf58 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.095); catalogued as COSV100314702; called by muse, mutect2, varscan2
- CALCR | c.987C>G p.F329L (on ENST00000649521 / NM_001164737.2; = p.F313L on NM_001742.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs199570255, COSV100810418, COSV100810790; called by muse, mutect2, varscan2
- CCDC180 | c.2274G>T p.E758D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100826582; called by muse, mutect2, varscan2
- CCDC39 | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99867435; called by muse, mutect2, varscan2
- CCDC40 | c.2048A>G p.H683R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100884232; called by muse, mutect2, varscan2
- CCDC73 | c.1260T>A p.Y420* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100066575; called by muse, mutect2, varscan2
- CCDC93 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100098426; called by muse, mutect2, varscan2
- CD1E | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63772615; called by muse, mutect2, varscan2
- CD70 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99835531; called by muse, mutect2, varscan2
- CDC42BPG | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100711971; called by muse, mutect2, varscan2
- CELF2 | c.497G>C p.G166A (on ENST00000416382 / NM_001025077.3; = p.G173A on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100256834; called by muse, mutect2, varscan2
- CENPJ | c.3576C>A p.F1192L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1335692817, COSV55045745; called by muse, mutect2, varscan2
- CGNL1 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV99847573; called by muse, mutect2, varscan2
- CLDN18 | c.88T>C p.W30R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480643; called by muse, mutect2
- CLSTN1 | c.1237A>T p.M413L (on ENST00000377298 / NM_001009566.3; = p.M403L on NM_014944.4) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV100790470; called by muse, mutect2, varscan2
- CNTF | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770282310, COSV100284335; called by muse, mutect2, varscan2
- COL7A1 | c.7799C>T p.S2600F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV99866128; called by muse, mutect2, varscan2
- CORIN | c.167G>C p.C56S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99903017; called by muse, mutect2, varscan2
- DCAF6 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100393982; called by muse, mutect2, varscan2
- DGKI | c.1904A>G p.D635G | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99932663; called by muse, mutect2, varscan2
- DGKI | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55965895, COSV99932667; called by muse, mutect2, varscan2
- DKK1 | c.670A>T p.R224W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100906485; called by muse, mutect2, varscan2
- DNAH7 | c.691C>G p.R231G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as COSV100414041, COSV56795178; called by muse, mutect2, varscan2
- DPP6 | c.1040C>A p.A347D (on ENST00000377770 / NM_001364500.2; = p.A285D on NM_001936.5) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100123414; called by muse, mutect2
- DTX1 | c.1589G>T p.R530I | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99921462; called by muse, mutect2, varscan2
- EDN1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs1367007262, COSV101040288; called by muse, mutect2, varscan2
- EHMT1 | c.3472G>T p.E1158* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as COSV101509598; called by muse, mutect2, varscan2
- EPN2 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV59061405; called by muse, mutect2, varscan2
- EPS8 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV99842699; called by muse, mutect2, varscan2
- ERICH3 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV100443531; called by muse, mutect2
- FAM47C | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1556333148, COSV100792326; called by muse, mutect2, varscan2
- FARP2 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 25/151 reads (17%) | catalogued as COSV99884009; called by muse, mutect2, varscan2
- FOXP2 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as COSV100646295; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs780370068, COSV63042223; called by muse, mutect2, varscan2
- FYTTD1 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV54083977, COSV99611386; called by muse, mutect2
- GRAMD1C | c.28-2A>C p.X10_splice | Splice Site (SNP) | VAF 28/177 reads (16%) | catalogued as COSV100822772; called by muse, mutect2, varscan2
- HEATR1 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV100857188, COSV63979413; called by muse, mutect2, varscan2
- HERC2 | c.3853-2A>T p.X1285_splice | Splice Site (SNP) | VAF 10/105 reads (10%) | catalogued as COSV99871365; called by muse, mutect2, varscan2
- HTR7 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99519046; called by muse, mutect2, varscan2
- IDH1 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV100576085, COSV99065748; called by muse, mutect2, varscan2
- IMPG2 | c.2767G>C p.E923Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51979870, COSV99516472; called by muse, mutect2, varscan2
- IRGC | c.878T>A p.L293* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV99746086; called by muse, mutect2, varscan2
- IRS1 | c.1465G>T p.G489C | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100524077; called by muse, mutect2, varscan2
- JAKMIP3 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100058717; called by muse, mutect2
- JAZF1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs368851837; called by muse, mutect2, varscan2
- KIF26B | c.5239G>A p.G1747S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1426179618, COSV100831688; called by muse, mutect2, varscan2
- KIFC1 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 14/328 reads (4%) | catalogued as COSV100995989, COSV65728936; called by muse, mutect2
- KLKB1 | c.1585G>T p.G529C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99249672; called by muse, mutect2, varscan2
- LAMA1 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs377172724, COSV101055815; called by muse, varscan2
- LILRA2 | c.1400T>A p.L467Q (on ENST00000391738 / NM_001130917.3; = p.L450Q on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99252873; called by muse, mutect2, varscan2
- LMBR1 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100626551, COSV62218327; called by muse, mutect2, varscan2
- LRMDA | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV100994425; called by muse, mutect2, varscan2
- LRP1 | c.2624G>A p.G875E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674669; called by muse, mutect2
- LRRC37A3 | c.3449G>A p.S1150N | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV100140877; called by muse, mutect2, varscan2
- MCCC1 | c.1010A>T p.N337I | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99659431; called by muse, mutect2, varscan2
- MXRA5 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475959; called by muse, mutect2, varscan2
- NBR1 | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV100357707; called by muse, mutect2
- NDRG1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV100105729; called by muse, mutect2
- NEDD4 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV100163372, COSV59062949; called by muse, mutect2, varscan2
- NEMP1 | c.824G>A p.R275Q (on ENST00000300128 / NM_001130963.2; = p.R202Q on NM_015257.3) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs767459890, COSV55662459; called by muse, mutect2, varscan2
- NKAIN2 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.768); catalogued as COSV100862485, COSV63661131, COSV63677546; called by muse, mutect2, varscan2
- NLRP6 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV100380951, COSV56458668; called by muse, varscan2
- NRK | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs372847875, COSV99686720; called by muse, mutect2, varscan2
- NTRK1 | c.1927G>T p.G643C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100693168, COSV62326011; called by muse, mutect2, varscan2
- OR10H2 | c.531T>G p.F177L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100008644; called by muse, mutect2, varscan2
- OR14I1 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100700433; called by muse, mutect2
- OR5M11 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs1287009725, COSV101602021; called by muse, mutect2, varscan2
- ORC1 | c.907T>G p.Y303D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV100856599; called by muse, mutect2, varscan2
- P2RY14 | c.245C>A p.S82* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99851728; called by muse, mutect2, varscan2
- PCDHB7 | c.581T>C p.L194S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99175934; called by muse, mutect2, varscan2
- PNLIP | c.165C>A p.F55L | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV100981644; called by muse, mutect2, varscan2
- POU2F3 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV52792918; called by muse, mutect2, varscan2
- PPP1R13L | c.2442C>G p.Y814* | Nonsense Mutation (SNP) | VAF 21/150 reads (14%) | catalogued as COSV100714679; called by muse, mutect2, varscan2
- PPP2R3B | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1452959170, COSV101180651; called by muse, mutect2, varscan2
- PRPF18 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100186982; called by muse, mutect2, varscan2
- PSMD1 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100433378; called by muse, mutect2
- PTPRB | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99316434; called by muse, mutect2, varscan2
- PWWP2B | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV100535641; called by muse, mutect2, varscan2
- RBBP8 | c.2402A>G p.K801R | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV100507099; called by muse, mutect2, varscan2
- REL | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 455/569 reads (80%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99691873; called by muse, mutect2, varscan2
- RUFY3 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99886921, COSV99887938; called by muse, mutect2, varscan2
- SALL2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs753189477, COSV58104956; called by muse, mutect2, varscan2
- SDK1 | c.5215-1G>A p.X1739_splice | Splice Site (SNP) | VAF 30/152 reads (20%) | catalogued as COSV67384574; called by muse, mutect2, varscan2
- SETX | c.4184A>C p.D1395A | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99808913; called by muse, mutect2, varscan2
- SHROOM3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533735013, COSV99933623; called by muse, mutect2, varscan2
- SIT1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99425715; called by muse, mutect2, varscan2
- SLC24A5 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100165106, COSV100165205; called by muse, mutect2, varscan2
- SLC30A8 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101438261; called by muse, mutect2, varscan2
- SLC45A4 | c.2233G>A p.E745K (on ENST00000517878 / NM_001286646.2; = p.E694K on NM_001080431.2) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs549733549, COSV50134689; called by muse, mutect2
- SMARCC2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99910896; called by muse, mutect2, varscan2
- SMIM7 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as rs746686844, COSV100701437; called by muse, mutect2, varscan2
- SPEG | c.6965G>T p.S2322I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100403428; called by muse, mutect2
- SPON1 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100115308; called by muse, mutect2, varscan2
- SPTA1 | c.6183G>C p.K2061N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100934070, COSV100934404, COSV63758126; called by muse, mutect2, varscan2
- STAMBPL1 | c.14T>G p.F5C | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.299); catalogued as COSV100905077; called by muse, mutect2, varscan2
- STING1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1043499198, COSV100423403; called by muse, mutect2
- TBC1D9 | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as COSV101464275; called by muse, mutect2, varscan2
- TP53 | c.565del p.A189Pfs*58 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as COSV52875466, COSV52908808, COSV53164619; called by mutect2, pindel, varscan2
- TPO | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs75965157, COSV100219868; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs775776262, COSV100389648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAJ45 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs1475202067; called by muse, mutect2
- TRH | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV100234746; called by muse, mutect2, varscan2
- TRPC1 | c.1141C>T p.H381Y (on ENST00000476941 / NM_001251845.2; = p.H347Y on NM_003304.4) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99858293; called by muse, mutect2, varscan2
- TRPM3 | c.692G>A p.R231H (on ENST00000357533 / NM_001366142.2; = p.R76H on NM_020952.6) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs766892514, COSV62467501; called by muse, mutect2
- TTC8 | c.220A>G p.I74V (on ENST00000338104 / NM_001288781.1; = p.I84V on NM_144596.4) | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs754944949, COSV100581077; called by muse, mutect2, varscan2
- UBOX5 | c.945C>G p.H315Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV99417467; called by muse, mutect2
- UQCRC2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as COSV99193273; called by muse, mutect2, varscan2
- YTHDF1 | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV100945544; called by muse, mutect2, varscan2
- ZNF106 | c.5550G>A p.W1850* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as COSV99782242; called by muse, mutect2, varscan2
- ZNF510 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV99793754; called by muse, mutect2, varscan2
- ZNF595 | c.795T>A p.F265L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100227467; called by muse, mutect2, varscan2
- ZNF700 | c.1343G>T p.C448F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54314607, COSV99583298; called by muse, mutect2, varscan2
- ZNF93 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as rs1469795594, COSV100652176; called by muse, mutect2, varscan2
- CCDC141 | c.2937dup p.V980Sfs*2 | Frame Shift Ins (INS) | VAF 27/127 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.261T>A p.S87R | Missense Mutation (SNP) | VAF 70/432 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- LHX1 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF804B | c.2627del p.G876Afs*14 | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1238G>T p.R413I | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ARL3 | c.531C>T p.V177= | Silent (SNP) | VAF 48/294 reads (16%) | catalogued as COSV99588968; called by muse, mutect2, varscan2
- ARMH3 | c.219G>A p.K73= | Silent (SNP) | VAF 28/175 reads (16%) | catalogued as COSV100228863; called by muse, mutect2, varscan2
- BEST2 | c.138G>C p.L46= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99244246; called by muse, mutect2, varscan2
- BSDC1 | c.1242A>G p.K414= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100344414; called by muse, mutect2, varscan2
- C17orf97 | c.726C>T p.L242= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100789284; called by muse, mutect2, varscan2
- C1QTNF9 | c.588T>A p.T196= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100129800; called by muse, mutect2, varscan2
- CASZ1 | c.747C>T p.G249= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV59739485; called by muse, mutect2, varscan2
- CCDC60 | c.219G>A p.L73= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100554678, COSV59540716; called by muse, mutect2, varscan2
- CCDC78 | c.1185C>T p.F395= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99557225; called by muse, mutect2, varscan2
- CD200R1L | c.738C>G p.L246= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV101236550, COSV68004233; called by muse, mutect2, varscan2
- CDC14B | c.84G>C p.V28= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99685308; called by muse, mutect2
- CDH19 | c.1128A>G p.V376= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100050966; called by muse, mutect2, varscan2
- CHST8 | c.1032C>T p.F344= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV52864140; called by muse, mutect2, varscan2
- CLEC14A | c.924C>A p.A308= | Silent (SNP) | VAF 56/187 reads (30%) | catalogued as COSV100643502; called by muse, mutect2, varscan2
- COL11A1 | c.4851C>T p.F1617= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as COSV62173713; called by muse, mutect2, varscan2
- COL1A1 | c.3300C>T p.G1100= | Silent (SNP) | VAF 29/208 reads (14%) | catalogued as rs1349721736, COSV56804749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNAL1 | c.696A>G p.E232= | Silent (SNP) | VAF 45/241 reads (19%) | catalogued as COSV100336365; called by muse, mutect2, varscan2
- CUBN | c.10860T>G p.T3620= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100912120; called by muse, mutect2, varscan2
- DCLK1 | c.975G>C p.P325= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs151019237, COSV55190671, COSV99709400; called by muse, mutect2, varscan2
- DDX19B | c.813G>A p.L271= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99849811; called by muse, mutect2, varscan2
- DNAH5 | c.6762G>A p.V2254= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as COSV99445639; called by muse, mutect2, varscan2
- FCRL5 | c.1950C>A p.L650= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV100708579; called by muse, mutect2, varscan2
- FRMPD1 | c.1938G>A p.E646= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs771936942, COSV100899351; called by mutect2, varscan2
- FSCB | c.558G>C p.S186= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as COSV100468910, COSV61219859; called by muse, mutect2, varscan2
- FSTL5 | c.2475C>G p.L825= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV100053112; called by muse, mutect2, varscan2
- GTF2IRD2B | c.27G>C p.L9= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.27C>A p.L9= | Silent (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2
- ILF3 | c.2046G>A p.A682= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs745697673, COSV99139388; called by muse, mutect2, varscan2
- KIF14 | c.1998G>T p.L666= | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- MAST4 | c.5118G>A p.L1706= (on ENST00000403625 / NM_001164664.2; = p.L1517= on NM_015183.3) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99843033; called by muse, mutect2, varscan2
- MBD1 | c.1560A>T p.V520= (on ENST00000269468 / NM_001323950.1; = p.V464= on NM_015844.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99495590; called by muse, mutect2, varscan2
- MYO10 | c.6120C>T p.I2040= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs969491126, COSV99944794; called by muse, mutect2
- NAV3 | c.546C>T p.Y182= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as COSV99887409; called by muse, mutect2, varscan2
- NEDD8 | c.27C>G p.T9= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs201497984, COSV99164596; called by muse, mutect2, varscan2
- NPAP1 | c.954C>A p.P318= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100274837, COSV61505716, COSV61510990; called by muse, mutect2, varscan2
- OR10Z1 | c.174C>A p.P58= | Silent (SNP) | VAF 73/403 reads (18%) | catalogued as COSV100778945, COSV100778952, COSV63525635; called by muse, mutect2, varscan2
- OR11H1 | c.87C>T p.I29= | Silent (SNP) | VAF 32/655 reads (5%) | catalogued as rs769046331, COSV53271992; called by muse, mutect2
- OR4X2 | c.504C>T p.H168= | Silent (SNP) | VAF 70/430 reads (16%) | catalogued as COSV100183166; called by muse, mutect2, varscan2
- PCDH12 | c.2973C>T p.G991= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99185897; called by muse, mutect2, varscan2
- PMFBP1 | c.1431G>A p.Q477= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs750176965, COSV99400288; called by muse, mutect2, varscan2
- PROC | c.747G>A p.L249= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as COSV52166237; called by muse, mutect2, varscan2
- PTX3 | c.720C>T p.L240= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs1231228813, COSV99904782; called by muse, mutect2, varscan2
- RAP1GAP | c.1527G>T p.V509= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99264794; called by muse, mutect2, varscan2
- SLC17A9 | c.510C>T p.T170= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as rs369346145; called by muse, mutect2, varscan2
- SLC22A9 | c.850C>A p.R284= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs769269694, COSV99654762; called by muse, mutect2, varscan2
- SNX13 | c.1794C>T p.T598= | Silent (SNP) | VAF 43/204 reads (21%) | catalogued as COSV101296792, COSV101296915; called by muse, mutect2, varscan2
- SPRR4 | c.90C>G p.P30= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs1326477256, COSV100044559; called by muse, mutect2, varscan2
- TIE1 | c.546C>A p.L182= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100992002, COSV65251141; called by muse, mutect2, varscan2
- TMEM177 | c.48G>A p.R16= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99733536; called by muse, mutect2, varscan2
- TTN | c.44067C>A p.I14689= (on ENST00000591111; = p.I7265= on NM_003319.4) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100596661; called by muse, mutect2
- TTN | c.17646C>A p.P5882= (on ENST00000591111; = p.P4955= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs753370006, COSV100596663; called by muse, mutect2, varscan2
- TUT4 | c.2322G>A p.Q774= | Silent (SNP) | VAF 55/229 reads (24%) | catalogued as COSV99931881; called by muse, mutect2, varscan2
- ZBTB7C | c.1329G>A p.T443= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1317273099, COSV100134272; called by muse, mutect2, varscan2
- ZNF251 | c.1623G>A p.E541= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV52957621; called by muse, mutect2, varscan2
- ZNF677 | c.1491T>C p.T497= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100447793; called by muse, mutect2, varscan2
- ZNF7 | c.963C>T p.L321= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs200004251, COSV100295673; called by muse, mutect2, varscan2
- ITGA3 | c.*166G>T | 3'UTR (SNP) | VAF 22/110 reads (20%) | catalogued as COSV99143324; called by muse, mutect2, varscan2
- LIM2 | c.175+11del | Intron (DEL) | VAF 27/139 reads (19%) | catalogued as rs776721409; called by mutect2, pindel, varscan2
- LIM2 | c.175+10C>T | Intron (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99702467; called by mutect2, varscan2
- MIR193B | n.25G>A | RNA (SNP) | VAF 13/248 reads (5%) | called by muse, mutect2
- MORF4 | n.365T>C | RNA (SNP) | VAF 30/178 reads (17%) | catalogued as rs766624732; called by muse, mutect2, varscan2
- NAA20 | c.53+575G>C | Intron (SNP) | VAF 34/263 reads (13%) | catalogued as COSV100131511; called by muse, mutect2, varscan2
- PLA2G2C | c.41-29C>A | Intron (SNP) | VAF 25/164 reads (15%) | catalogued as COSV99930207; called by muse, mutect2, varscan2
- PYGO1 | c.*2C>G | 3'UTR (SNP) | VAF 28/149 reads (19%) | catalogued as COSV100114510; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23872C>A | Intron (SNP) | VAF 17/123 reads (14%) | catalogued as COSV101043029; called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222196 C>T | 5'Flank (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- USH1C | c.1285-3962G>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99139403; called by muse, mutect2, varscan2
